Somatic mutation profile of tumor specimen TCGA-VS-A9UM-01A (aliquot TCGA-VS-A9UM-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 39.0 years (14,255 days).
Specimen TCGA-VS-A9UM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5254533c-4bd9-4f15-a997-569634cf3590.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UM-10A (Blood Derived Normal), aliquot TCGA-VS-A9UM-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71c87d21-32f0-4584-b7f8-413b8b75bf69

The open-access MAF lists 81 somatic variants for this specimen: 55 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 42, Silent 26, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 23/33 reads (70%) | catalogued as rs1553646284, COSV56230759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAMTA1 | c.4921C>T p.R1641* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs1057523792, COSV100348375, COSV100348424; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EBF3 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs1057519522, COSV100799313, COSV100799501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGO2 | c.291G>T p.R97S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99595879; called by muse, mutect2, varscan2
- B3GNT3 | c.1094G>C p.C365S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100427603; called by muse, mutect2, varscan2
- BMPR2 | c.77-2A>T p.X26_splice | Splice Site (SNP) | VAF 17/77 reads (22%) | catalogued as COSV101001542; called by muse, mutect2, varscan2
- BNIP5 | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101465164; called by muse, mutect2
- BTBD10 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.099); catalogued as COSV99533682; called by muse, mutect2, varscan2
- C2CD2L | c.1418A>T p.E473V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100371294; called by muse, mutect2, varscan2
- CASP7 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs376348175; called by muse, mutect2, varscan2
- CDH4 | c.2138G>C p.C713S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV100849061; called by muse, mutect2
- CELSR1 | c.5314G>A p.G1772R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418671; called by muse, mutect2, varscan2
- CHD6 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 27/43 reads (63%) | catalogued as COSV58557334; called by muse, mutect2, varscan2
- COQ6 | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.145); catalogued as COSV99473820, COSV99473989; called by muse, mutect2, varscan2
- CPNE9 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.965); catalogued as COSV99808128, COSV99808322; called by muse, mutect2, varscan2
- CTHRC1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100372999; called by muse, mutect2, varscan2
- DNAH9 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV99306325; called by muse, mutect2, varscan2
- EIF4G2 | c.1495C>G p.P499A | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV101150916; called by muse, mutect2
- HCAR1 | c.958C>G p.R320G | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs778522723, COSV100811646, COSV63671023; called by muse, mutect2
- HIVEP3 | c.3390G>C p.Q1130H | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV99912966; called by muse, mutect2
- HNRNPR | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100164571; called by muse, mutect2, varscan2
- HOOK3 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV100295583; called by muse, mutect2, varscan2
- IGSF10 | c.2662C>T p.Q888* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV56792087, COSV99180803; called by muse, mutect2, varscan2
- KMT2B | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV99386112; called by muse, varscan2
- LY75 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs780326292, COSV99716573; called by muse, mutect2, varscan2
- MAGEA4 | c.442T>A p.F148I | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99367547; called by muse, mutect2, varscan2
- MAGEC1 | c.2878C>A p.L960I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as COSV53575703, COSV99595860; called by muse, mutect2, varscan2
- MGAM | c.4777G>C p.D1593H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV101527539; called by muse, mutect2, varscan2
- MKI67 | c.1970-1G>C p.X657_splice | Splice Site (SNP) | VAF 7/107 reads (7%) | catalogued as COSV100896658; called by muse, mutect2
- MYOM3 | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1234024694, COSV100293044; called by muse, mutect2, varscan2
- NMT2 | c.246+1G>C p.X82_splice | Splice Site (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100975569; called by muse, mutect2
- NPAS3 | c.1033T>G p.Y345D (on ENST00000356141 / NM_001164749.2; = p.Y313D on NM_022123.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100640286; called by muse, mutect2, varscan2
- NSD1 | c.4807G>T p.V1603F | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100729370; called by muse, mutect2, varscan2
- PDGFRA | c.1916A>G p.Q639R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99956816; called by muse, mutect2, varscan2
- PHKB | c.2831G>A p.R944Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as rs770163832, COSV54527736; called by muse, mutect2, varscan2
- PLCH1 | c.4777G>A p.A1593T (on ENST00000340059 / NM_001130960.2; = p.A1585T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100397191; called by muse, mutect2, varscan2
- POLE | c.2521A>G p.N841D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV100267111; called by muse, mutect2, varscan2
- PPP3R2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201878659, COSV62456005; called by muse, mutect2, varscan2
- RBM39 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); catalogued as rs1215706067, COSV53615480; called by muse, mutect2, varscan2
- RPE | c.326G>A p.R109Q (on ENST00000359429 / NM_001318926.1; = p.R41Q on NM_006916.2) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs535548466, COSV63278901; called by muse, mutect2, varscan2
- SLC14A2 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs145237117; called by muse, mutect2
- SLC25A43 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99474602; called by muse, mutect2, varscan2
- TACC3 | c.1749C>A p.S583R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1259677695, COSV100508786; called by muse, mutect2, varscan2
- TDRD1 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV52587324, COSV52590970, COSV99314678; called by muse, mutect2, varscan2
- TMEM132E | c.1455G>C p.E485D (on ENST00000321639; = p.E575D on NM_001304438.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV100396452; called by muse, mutect2, varscan2
- TMEM63C | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368880696; called by muse, mutect2, varscan2
- TRIM46 | c.116T>A p.M39K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99825992; called by muse, mutect2
- TTN | c.46114G>A p.E15372K (on ENST00000591111; = p.E7948K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | PolyPhen probably damaging (0.994); catalogued as COSV100617667; called by muse, mutect2, varscan2
- TTN | c.28127C>T p.A9376V (on ENST00000591111; = p.A8449V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | PolyPhen benign (0.151); catalogued as rs767793508, COSV100617670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.8704G>A p.E2902K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, varscan2
- ANK3 | c.8680_8684del p.K2894* | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by pindel, varscan2
- LIG3 | c.787_798delinsG p.L263Afs*10 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by pindel, varscan2*
- MYO1G | c.973_978del p.S325_L326del | In Frame Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- SLC16A1 | c.468_477del p.F157Lfs*20 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- SLC22A12 | c.840_859del p.E281Hfs*31 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- ARMC4 | c.63C>G p.L21= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100536981, COSV59463128; called by muse, mutect2, varscan2
- DZANK1 | c.1641C>T p.F547= (on ENST00000262547 / NM_001099407.1; = p.F354= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/96 reads (58%) | catalogued as COSV99362639; called by muse, mutect2, varscan2
- EPAS1 | c.2124G>T p.L708= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99763305; called by muse, mutect2, varscan2
- ERP44 | c.766T>C p.L256= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs768142376, COSV99315939, COSV99316486; called by muse, varscan2
- FEZ2 | c.477C>T p.L159= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100002182; called by muse, mutect2, varscan2
- GEMIN5 | c.345A>G p.L115= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV99594012; called by muse, mutect2, varscan2
- HRH4 | c.321C>T p.L107= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99907886; called by muse, mutect2, varscan2
- KIAA1549 | c.5076C>T p.D1692= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as rs768260879, COSV99651039; called by muse, mutect2, varscan2
- KLF4 | c.1368C>T p.F456= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1000148821; called by muse, mutect2
- LAMB3 | c.1461C>T p.N487= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100620393; called by muse, mutect2, varscan2
- LRFN1 | c.1383C>T p.S461= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs369841857; called by muse, mutect2, varscan2
- MVD | c.1144C>T p.L382= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV55368548; called by muse, mutect2, varscan2
- PCDHB10 | c.228C>G p.L76= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV99504487; called by muse, mutect2, varscan2
- RFX4 | c.285C>T p.T95= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100774696; called by muse, mutect2, varscan2
- RIMBP2 | c.57G>A p.L19= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV99899719; called by muse, mutect2, varscan2
- RNF17 | c.1011C>T p.Y337= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs141654694; called by muse, mutect2, varscan2
- RNPEP | c.1314C>G p.L438= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV99821565; called by muse, mutect2, varscan2
- SEPHS2 | c.621G>C p.G207= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV101529330, COSV72100701; called by muse, mutect2, varscan2
- SH2D3C | c.672C>T p.R224= (on ENST00000314830 / NM_170600.3; = p.R67= on NM_005489.4) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100137033; called by muse, mutect2, varscan2
- STAU1 | c.1209C>T p.F403= (on ENST00000371856 / NM_001319135.1; = p.F322= on NM_004602.3) | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100574397; called by muse, mutect2, varscan2
- SUV39H1 | c.645C>T p.A215= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs868959716, COSV100551794; called by muse, mutect2, varscan2
- TBR1 | c.417C>T p.I139= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV67417670; called by muse, mutect2, varscan2
- UBE4B | c.2301C>G p.L767= (on ENST00000343090 / NM_001105562.3; = p.L638= on NM_006048.5) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99476899; called by muse, mutect2, varscan2
- WBP11 | c.1524C>A p.R508= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV99660746; called by muse, mutect2, varscan2
- ZNF813 | c.1044T>A p.L348= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV101124888; called by muse, mutect2
- ZNRF4 | c.348G>A p.L116= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1217314436, COSV55774781; called by muse, mutect2, varscan2
